TCGA case TCGA-DK-A3IM — Bladder Urothelial Carcinoma (TCGA-BLCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Transitional Cell Papillomas and Carcinomas; Primary site: Bladder; Tissue source site: Memorial Sloan Kettering. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/41b59716-116f-4942-8b63-409870a87e26

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 76 years; Vital status: Dead; Days to death: 248 days.

Diagnoses (3)
1. Transitional cell carcinoma (the primary disease): ICD-O-3 morphology code: 8120/3; ICD-10 code: C67.9; Tissue or organ of origin: Bladder, NOS; Site of resection or biopsy: Bladder, NOS; Classification of tumor: primary; Age at diagnosis: 77.0 years (28,106 days); Year of diagnosis: 2011; Method of diagnosis: Biopsy; AJCC staging edition: 6th; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 248 days.
   Pathology details: Consistent pathology review: No; Lymph nodes positive: 0; Lymph nodes tested: 8.
2. Recurrence of diagnosis 1 (Transitional cell carcinoma), site: Lymph node, NOS. Age at diagnosis: 77.5 years (28,307 days); Days to diagnosis: 201 days; Prior treatment: Yes.
3. Metastasis of diagnosis 1 (Transitional cell carcinoma), site: Lung, NOS. Age at diagnosis: 77.5 years (28,307 days); Days to diagnosis: 201 days; Prior treatment: Yes.

Follow-up (4 entries)
- Day 201 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 201 days.
- Day 201 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Lymph node, NOS; Days to recurrence: 201 days.
- Days to follow up: 238 days; Disease response: With Tumor.
- Follow-up contact recording only the day: day 248.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 92.1 kg; Height: 174.6 cm; BMI: 30.2.

Exposures
- Occupation type: Sales, Marketing and Public Relations Professionals.
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 8; Tobacco smoking quit year: 1961; Age at onset: 19.

Family history
- Relative with cancer history: yes; Relationship type: Child; Relationship primary diagnosis: Leukemia.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DK-A3IM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 480 mg.
  Slide TCGA-DK-A3IM-01A-01-TSA: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 85; Percent normal cells: 5; Percent necrosis: 20; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 2.
- Sample TCGA-DK-A3IM-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DK-A3IM-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: With tumor; Occupation current: Retired; Occupation primary: Businessman; Occupation primary industry: Business; Tobacco smoking history indicator: 3; Histologic diagnosis: Muscle invasive urothelial carcinoma (pT2 or above); Histologic subtype: Papillary; Anatomic organ subdivision: Bladder - NOS; Method initial path diagnosis: Endoscopic Biopsy; Lymph nodes examined: Yes; Incidental prostate cancer indicator: No.
- Follow-up form 1: Lost to follow-up: No; Tumor status: With tumor; Treatment outcome first course: Complete Remission/Response.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 248 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 248 days; disease-free interval: event (new tumor event after initially disease-free), 201 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 201 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DK-A3IM-01A-11D-A20B-01): tumor purity 0.83, ploidy 2.8, whole-genome doublings 1.
